Gene-level copy-number profile of tumor specimen TCGA-DX-A8BK-01A from TCGA case TCGA-DX-A8BK, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 61.3 years (22,407 days).
Specimen TCGA-DX-A8BK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.a29388fa-91ef-4d07-b57f-abac6f64fe02.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A8BK-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ef833a02-a02a-4502-a505-36e64aa2500d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 86; copy number 1: 1,224; copy number 2: 12,794; copy number 3: 23,051; copy number 4: 13,392; copy number 5: 3,124; copy number 6: 3,671; copy number 7: 743; copy number 8: 1,128; copy number 9: 279; copy number 10: 125; copy number 11: 26; copy number 12: 50; copy number 15: 93; copy number 18: 25.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A8BK-01A-11D-A37B-01): tumor purity 0.43, ploidy 3.31, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 36 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:30,202,630–30,429,758, 9 genes (within-gene range 0–2): KATNAL1, RNU6-64P, PRDX2P1, LINC00427, LINC00426, AL356750.1, AL161893.1, LINC01058, UBE2L5.
- chr13:37,220,860–37,221,246, 1 gene: RPS12P24.
- chr13:37,534,940–37,598,844, 2 genes: LINC00547, POSTN.
- chr13:48,303,744–48,599,436, 1 gene (within-gene range 0–1): RB1.
- chr13:48,389,567–49,528,981, 23 genes: LPAR6, Metazoa_SRP, RCBTB2, AL157813.2, AL157813.1, LINC01077, LINC00462, CYSLTR2, PSME2P2, AL161421.1, FNDC3A, RNU6-60P, RAD17P2, RNY3P2, COX7CP1, OGFOD1P1, MLNR, AL137000.1, CDADC1, CAB39L, SETDB2, SNRPGP14, PHF11.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,318 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:106,160,417–108,855,005, 45 genes, copy number 8 (within-gene range 6–8): AC131237.1, AC079382.1, AC079382.2, LINC00882, Y_RNA, AC080097.1, Y_RNA, FCF1P3, MTND4P16, MTND4LP3, MTND3P6, MTCO3P35, MTATP6P22, MTND5P16, MTND6P6, MTCO1P35, MTND1P16, MTND2P14, RNU6-1308P, AC117435.1, AC074043.1, DUBR, AC063944.1, CSP2, AC063944.2, CCDC54, LINC01990, BBX, LINC00636, LINC00635, AC012020.1, CD47, LINC01215, IFT57, HHLA2, HNRNPA1P17, MYH15, AC069499.1, CIP2A, SNORA70, AC069499.2, DZIP3, AC092185.1, RETNLB, TRAT1.
- chr3:109,648,107–117,139,389, 115 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr3:121,431,427–129,046,921, 187 genes, copy number 7 (broad region; genes not listed).
- chr3:172,443,291–172,725,038, 9 genes, copy number 7: GHSR, TNFSF10, AC007919.1, LINC02068, SLC31A1P1, NCEH1, AC007919.2, RNU6-547P, AC108667.2.
- chr3:176,415,439–176,867,838, 1 gene, copy number 7 (within-gene range 4–7): LINC01208.
- chr3:176,763,233–176,817,001, 2 genes, copy number 7: RNA5SP147, LINC01209.
- chr3:177,683,627–182,035,644, 80 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr4:23,560,923–25,418,498, 21 genes, copy number 11 (within-gene range 5–11): AC093607.1, ERVH-1, PPARGC1A, AC092834.1, DHX15, MIR573, RN7SL16P, ATP5MGP3, LINC02473, AC006390.1, HNRNPA1P65, SOD3, CCDC149, LGI2, SEPSECS, SEPSECS-AS1, PI4K2B, AC104662.1, U2, ZCCHC4, ANAPC4.
- chr4:64,836,361–65,024,485, 2 genes, copy number 8 (within-gene range 3–8): AC104689.2, LINC02232.
- chr5:58,198–23,689,386, 383 genes, copy number 8–10 (broad region; genes not listed).
- chr5:23,972,188–23,994,603, 3 genes, copy number 10: AC026784.1, ADH5P5, Y_RNA.
- chr5:25,701,217–26,484,711, 7 genes, copy number 8: RNU6-374P, AC022418.1, MSNP1, AC113370.1, RNU4-43P, AC025475.1, AC025475.2.
- chr5:28,548,135–28,809,291, 3 genes, copy number 8 (within-gene range 6–8): AC008825.1, AC109472.1, RNU6-909P.
- chr5:94,152,966–121,359,869, 330 genes, copy number 7–10 (within-gene range 5–10) (broad region; genes not listed).
- chr9:83,938,311–84,340,758, 10 genes, copy number 7: C9orf64, HNRNPK, MIR7-1, AL354733.3, RMI1, Y_RNA, AL390838.1, AL390838.2, SLC28A3, AL356134.1.
- chr9:86,632,147–86,696,496, 1 gene, copy number 7 (within-gene range 5–7): AL353613.1.
- chr11:87,037,844–87,817,567, 16 genes, copy number 7–9 (within-gene range 2–9): TMEM135, XIAPP2, AP002967.1, AP001102.1, AP000811.1, PSMA2P1, AP003497.1, AP003497.2, AP001784.1, RNU6-1135P, U6, LINC02711, AP000756.1, MTCYBP41, AP000676.2, AP000676.3.
- chr11:87,879,473–87,917,999, 2 genes, copy number 7: AP000676.4, AP000676.1.
- chr12:19,404,045–19,720,801, 1 gene, copy number 8 (within-gene range 6–8): AEBP2.
- chr12:19,508,904–20,012,261, 5 genes, copy number 8 (within-gene range 2–8): AC091805.1, AC137561.1, RNU1-146P, AC024901.1, TCP1P3.
- chr15:94,841,059–101,933,350, 159 genes, copy number 10–18 (within-gene range 3–18) (broad region; genes not listed).
- chr16:11,555–23,216,883, 833 genes, copy number 8 (broad region; genes not listed).
- chr17:142,789–1,463,162, 41 genes, copy number 7–10 (within-gene range 6–10): DOC2B, LINC02091, RPH3AL, AC129507.4, AC129507.1, AC129507.2, AC129507.3, AC141424.1, C17orf97, RFLNB, AC015853.2, VPS53, AC015853.3, AC015853.1, AC027455.1, RPS4XP17, TLCD3A, GEMIN4, DBIL5P, GLOD4, AC087392.3, MRM3, AC087392.4, AC087392.5, NXN, AC087392.2, AC087392.1, AC036164.1, TIMM22, ABR, MIR3183, Metazoa_SRP, AC016292.2, AC016292.1, AC144836.1, BHLHA9, TRARG1, YWHAE, AC032044.2, CRK, AC032044.1.
- chr17:2,366,589–3,696,240, 60 genes, copy number 7: AC006435.3, AC006435.2, MNT, AC006435.1, METTL16, AC006435.4, AC006435.5, RN7SL33P, EIF4A1P9, PAFAH1B1, SAMD11P1, AC015799.1, RN7SL608P, AC005696.2, AC005696.3, CLUH, MIR6776, AC005696.1, AC005696.4, CCDC92B, MIR1253, hsa-mir-1253, RAP1GAP2, AC015921.1, OR1D5, OR1D2, OR1E3, OR1G1, AC090282.1, OR1P1, OR1A2, OR1A1, OR1D4, OR1D3P, OR3A2, OR3A1, OR3A4P, AC087498.1, OR1AC1P, OR1R1P, OR1E1, OR3A3, OR1E2, AC025125.1, SPATA22, ASPA, TRPV3, TRPV1, AC027796.5, AC027796.3, AC027796.1, SHPK, AC027796.2, CTNS, AC027796.4, TAX1BP3, P2RX5-TAX1BP3, AC132942.1, EMC6, P2RX5.
- chr17:3,721,628–3,726,699, 2 genes, copy number 7: AC116914.2, HASPIN.

Autosomal genes at a single copy (total copy number 1): 1,088. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
